Gene-level copy-number profile of tumor specimen HCM-WCMC-0747-C50-01A from HCMI case HCM-WCMC-0747-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 43.2 years (15,793 days).
Specimen HCM-WCMC-0747-C50-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 327b7b22-4597-4c39-bd92-8751784ccc72.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0747-C50-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/684b8be7-5903-4241-a71d-4cd6d095ce69

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 377; copy number 1: 1,902; copy number 2: 49,486; copy number 3: 5,341; copy number 4: 1,268; copy number 5: 7; copy number 6: 3; copy number 7: 3.

Homozygous deletions (total copy number 0; autosomes only): 377 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:34,792,999–34,795,747, 1 gene (within-gene range 0–2): GJA4.
- chr1:47,137,435–47,149,735, 1 gene (within-gene range 0–2): CYP4A22.
- chr1:47,183,582–47,232,220, 3 genes: PDZK1IP1, TAL1, AL135960.1.
- chr1:143,419,625–143,498,767, 5 genes: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1.
- chr1:143,905,487–143,934,776, 2 genes (within-gene range 0–4): AC246680.1, RPL22P5.
- chr3:49,640,483–49,641,769, 1 gene (within-gene range 0–3): BSN-AS1.
- chr9:21,201,469–21,209,779, 3 genes (within-gene range 0–2): IFNA7, IFNA10, IFNWP18.
- chr11:1,469,457–1,501,247, 1 gene: MOB2.
- chr11:49,817,778–49,826,724, 2 genes: AC130364.1, AC130364.2.
- chr11:75,758,455–75,801,535, 3 genes (within-gene range 0–2): AP001922.1, DGAT2, AP001922.3.
- chr12:54,058,254–54,125,992, 5 genes (within-gene range 0–3): FLJ12825, AC023794.3, AC023794.2, FAM242C, Y_RNA.
- chr12:54,126,082–54,147,485, 1 gene (within-gene range 0–3): LINC02381.
- chr15:57,706,695–57,782,762, 2 genes (within-gene range 0–2): POLR2M, AC090651.1.
- chr16:32,250,620–32,265,514, 3 genes: AC133485.3, TP53TG3D, AC133485.2.
- chr16:33,808,778–33,875,468, 7 genes: AC136428.3, AC136428.1, AC140658.6, AC140658.7, AC140658.2, IGHV3OR16-11, AC140658.3.
- chr16:46,469,341–52,677,747, 151 genes (broad region; genes not listed).
- chr16:66,908,122–67,009,758, 9 genes: CDH16, RRAD, CIAO2B, CES2, AC009084.1, AC009084.3, CES3, CES4A, AC009084.2.
- chr16:76,264,776–80,572,808, 70 genes (within-gene range 0–1) (broad region; genes not listed).
- chr16:80,627,551–80,628,379, 1 gene (within-gene range 0–1): AC092332.1.
- chr16:81,445,170–83,800,640, 35 genes (within-gene range 0–1): CMIP, AC092139.1, PPIAP51, AC092139.2, MIR7854, MIR6504, AC092135.2, AC092135.1, AC092135.3, AC099524.1, PLCG2, RN7SKP176, AC092142.2, SDR42E1, HSD17B2, AC092142.1, MTCYBP28, MPHOSPH6, AC138304.1, RN7SKP190, AC009117.1, AC009117.2, CDH13, MIR8058, AC099506.2, AC099506.1, AC099506.3, RN7SL134P, AC125793.1, AC009142.1, MIR3182, AC009063.3, AC009063.4, AC009063.2, AC009063.1.
- chr16:85,899,162–87,602,190, 55 genes (within-gene range 0–1): IRF8, MIR6774, AC092723.5, LINC02132, AC092723.4, AC092723.1, AC092723.2, AC135012.1, AC135012.2, AC135012.3, LINC01082, LINC01081, Y_RNA, LINC02135, LINC00917, AC092327.2, AC092327.1, FENDRR, FOXF1, AC009108.3, AC009108.1, MTHFSD, FLJ30679, FOXC2-AS1, FOXC2, FOXL1, AC009108.4, AC009108.2, AC009154.1, AC009154.2, LINC02188, LINC02189, AC093519.2, AC093519.1, LINC02181, AC106745.1, C16orf95, AC136285.3, AC136285.1, AC136285.2, AC010531.4, AC010531.2, AC010531.8, AC010531.1, AC010531.6, AC010531.7, FBXO31, AC010531.5, MAP1LC3B, AC010531.3, ZCCHC14, AC105429.2, AC105429.1, AC092720.3, AC092720.2.
- chr16:88,382,959–88,440,757, 1 gene: ZNF469.
- chr19:51,155,288–51,155,624, 1 gene (within-gene range 0–2): AC063977.6.
- chr19:54,696,604–54,867,207, 13 genes (within-gene range 0–2): LILRP1, AC245128.2, LILRP2, KIR3DL3, AC245128.1, KIR2DL3, KIR2DP1, KIR2DL1, KIR3DP1, KIR2DL4, KIR3DL1, KIR2DS4, KIR3DL2.
- chr22:29,720,003–29,731,833, 1 gene (within-gene range 0–2): CABP7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:65,463,071–65,463,438, 1 gene, copy number 7: AC114501.3.
- chr9:40,883,634–40,883,763, 1 gene, copy number 6: AL353626.2.
- chr10:95,141,925–95,168,425, 1 gene, copy number 7: AL157834.4.
- chr12:132,457,160–132,462,856, 2 genes, copy number 5: AC079031.1, AC079031.2.
- chr17:28,755,978–28,855,232, 4 genes, copy number 5 (within-gene range 3–5): FAM222B, RPL31P58, Y_RNA, AC024267.2.
- chr17:67,991,099–67,996,469, 1 gene, copy number 6: C17orf58.
- chr18:51,028,394–51,085,045, 1 gene, copy number 5 (within-gene range 2–5): SMAD4.
- chr21:44,133,610–44,210,114, 1 gene, copy number 7 (within-gene range 2–7): GATD3A.

Autosomal genes at a single copy (total copy number 1): 1,902. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
